Somatic mutation profile of tumor specimen TCGA-DU-A76L-01A (aliquot TCGA-DU-A76L-01A-11D-A32B-08) from TCGA case TCGA-DU-A76L, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 54.3 years (19,823 days).
Specimen TCGA-DU-A76L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6eafb65-7fc0-4d95-9cb7-9629d955c3ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A76L-10A (Blood Derived Normal), aliquot TCGA-DU-A76L-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8afe6a0e-2306-494f-a2d8-4ca642f1e78c

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 24, Silent 10, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs786205745, COSV59748365, COSV59754731; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1S | c.2674G>A p.V892M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs146823170; called by muse, mutect2, varscan2
- CCSER1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774767718, COSV61465180; called by muse, mutect2, varscan2
- DEPDC1 | c.1841G>A p.R614H (on ENST00000456315 / NM_001114120.3; = p.R330H on NM_017779.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs752745984, COSV63957490; called by muse, mutect2, varscan2
- ELAC2 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100568438; called by muse, varscan2
- FRAS1 | c.11711C>T p.A3904V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs750578354, COSV53594701; called by muse, varscan2
- GABRR1 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.984); catalogued as rs192148367, COSV101033710, COSV101033839; called by muse, varscan2
- GPA33 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs749764347, COSV100901000; called by muse, mutect2, varscan2
- GPRIN3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.34); catalogued as rs187145478, COSV100310689; called by muse, mutect2, varscan2
- HLTF | c.2726T>G p.L909R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026788; called by muse, mutect2, varscan2
- LCE3A | c.168G>T p.R56S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as rs758179270, COSV100175103, COSV59551038; called by muse, mutect2, varscan2
- LVRN | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369192779; called by muse, mutect2, varscan2
- MTPAP | c.1646T>G p.F549C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99553972; called by muse, mutect2, varscan2
- OR2T27 | c.718A>C p.T240P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100788200; called by muse, mutect2, varscan2
- OR2T8 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178198; called by muse, mutect2, varscan2
- OR5V1 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV101011206; called by muse, mutect2, varscan2
- PDE4D | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as rs777001089, COSV101550435; called by muse, mutect2, varscan2
- PDE8A | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as rs141263963; called by muse, mutect2, varscan2
- PEAR1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs267598083, COSV52770521, COSV99441136; called by muse, mutect2, varscan2
- PRPF8 | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs755193337, COSV100517368; called by muse, mutect2, varscan2
- PSAP | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as rs754208657, COSV56498982; called by muse, mutect2, varscan2
- SI | c.2160-1G>T p.X720_splice | Splice Site (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100015002; called by muse, mutect2, varscan2
- SMYD5 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV99242776; called by muse, mutect2
- TNS4 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs140343246; called by muse, mutect2, varscan2
- TOGARAM1 | c.1212C>G p.D404E | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100753067; called by muse, mutect2, varscan2
- ELMOD2 | c.3_6del p.M1_?2 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | called by pindel, varscan2
- NF1 | c.1754_1758del p.L585* | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- RARB | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- C9 | c.1179A>G p.E393= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV54678411; called by muse, mutect2, varscan2
- CX3CR1 | c.426C>T p.T142= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs377299023; called by muse, mutect2, varscan2
- MDN1 | c.2154G>A p.P718= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs527741590, COSV101021116; called by muse, mutect2, varscan2
- MYO7A | c.3987C>T p.Y1329= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs560284703, COSV101289096, COSV68686491; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHGB3 | c.1437C>T p.P479= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV53910500, COSV53910759; called by muse, mutect2, varscan2
- PDILT | c.237G>A p.A79= | Silent (SNP) | VAF 115/372 reads (31%) | catalogued as rs555849933, COSV56701641; called by muse, mutect2, varscan2
- PTPRM | c.699C>T p.I233= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV59850219; called by muse, mutect2, varscan2
- RNF32 | c.258G>A p.P86= | Silent (SNP) | VAF 29/164 reads (18%) | catalogued as rs770206152, COSV100311355; called by muse, mutect2, varscan2
- SLC11A1 | c.1431C>T p.C477= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs769585872, COSV99262052; called by muse, mutect2, varscan2
- TMEM132D | c.480C>T p.S160= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs201922398, COSV70594100; called by muse, mutect2, varscan2
